Gene-level copy-number profile of specimen HCM-CSHL-0740-C18-85N from HCMI case HCM-CSHL-0740-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.8 years (24,398 days).
Specimen HCM-CSHL-0740-C18-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 383a6ced-d8af-4161-92bd-ee7690eb5742.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0740-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/1f008b03-25f9-4c17-9589-6e1b6a0fbb5f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 918; copy number 3: 512; copy number 4: 20,867; copy number 5: 6,933; copy number 6: 19,500; copy number 7: 6,187; copy number 8: 852; copy number 9: 1,111; copy number 10: 36; copy number 11: 1,469; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,617 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:68,496,676–76,637,339, 88 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr1:143,461,221–143,652,215, 8 genes, copy number 10: AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P.
- chr1:176,305,672–176,306,095, 1 gene, copy number 9: AL591043.1.
- chr2:545,805–868,608, 11 genes, copy number 9: LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115.
- chr2:2,707,368–3,377,830, 7 genes, copy number 9 (within-gene range 8–9): AC011995.2, AC018685.1, AC011995.1, LINC01250, AC019118.2, AC019118.1, EIPR1.
- chr2:3,379,675–7,077,916, 48 genes, copy number 9: TRAPPC12, TRAPPC12-AS1, AC114810.1, ADI1, AC231981.1, AC108488.1, AC108488.2, RNASEH1, RNASEH1-AS1, RPS7, COLEC11, AC010907.2, TMSB4XP2, ALLC, GAPDHP48, AC010907.1, DCDC2C, LINC01304, AC012445.1, NPM1P48, LINC01249, AC092169.1, RNU6-649P, AC073143.1, AC107057.1, LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810, SILC1, MIR7158, AC017053.1, LINC01247, LINC01824, PIK3CDP1, MIR7515HG, AC097517.1, MIR7515, LINC00487, NRIR, CMPK2, RSAD2, AC017076.1, GRASLND, RNF144A, AC068481.1.
- chr2:7,260,871–10,302,485, 60 genes, copy number 9: AC010904.2, AC010904.1, AC013460.1, RNU6ATAC37P, AC092580.4, AC092580.2, LINC01871, AC092580.3, AC092580.1, AC007463.1, LINC00298, AC007463.2, LINC00299, U91324.1, LINC01814, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B, AC010969.2, AC010969.3, GRHL1, AC010969.1, AC104794.4, AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1, RRM2, AC007240.1, MIR4261, RN7SL66P, AC007240.3, AC007240.2.
- chr2:11,102,142–11,234,094, 5 genes, copy number 9: RPL6P4, AC062028.1, C2orf50, SLC66A3, RNU6-1081P.
- chr2:11,351,627–11,642,788, 10 genes, copy number 9 (within-gene range 8–9): PPIAP60, AC099344.1, LINC00570, AC099344.2, E2F6, GREB1, RNA5SP84, MIR4429, RNU2-13P, 5S_rRNA.
- chr2:11,658,178–11,827,409, 8 genes, copy number 9: NTSR2, CDK8P1, AC106875.2, LPIN1, AC106875.1, AC012456.1, AC012456.2, MIR548S.
- chr2:12,598,987–12,742,734, 5 genes, copy number 9: AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125.
- chr2:17,284,292–19,348,067, 16 genes, copy number 9: ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1, KCNS3, AC079802.1, AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P, AC106053.1, LINC01376.
- chr2:19,458,220–21,970,959, 47 genes, copy number 9 (within-gene range 8–10): AC010096.1, LINC01808, AC019055.1, CISD1P1, LINC00954, TTC32, AC013400.1, WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3, LDAH, LINC02850, AC115619.1, APOB, AC010872.1, TDRD15, AC067959.1, AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822, RN7SL117P.
- chr2:23,018,125–23,708,611, 6 genes, copy number 9 (within-gene range 8–9): AC018467.1, AC012506.1, AC012506.3, AC012506.2, AC012506.4, KLHL29.
- chr2:23,616,499–24,919,839, 32 genes, copy number 9: AC011239.2, AC009242.1, ATAD2B, PGAM1P6, RPS13P4, UBXN2A, SDHCP3, RN7SL610P, MFSD2B, WDCP, RNU6-370P, FKBP1B, SF3B6, FAM228B, TP53I3, PFN4, AC008073.3, AC008073.2, FAM228A, AC008073.1, ITSN2, AC009228.1, AC009228.2, HMGN2P20, RPL36AP13, NCOA1, RNA5SP88, RNU6-936P, PTRHD1, CENPO, ADCY3, AC012073.1.
- chr2:25,160,853–29,189,643, 122 genes, copy number 9–10 (broad region; genes not listed).
- chr2:30,051,066–30,210,307, 5 genes, copy number 9: AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5.
- chr2:30,343,222–30,361,010, 2 genes, copy number 9: AC109642.1, LINC01936.
- chr2:31,522,480–31,580,938, 2 genes, copy number 9: SRD5A2, AL133247.1.
- chr2:95,145,000–95,184,317, 2 genes, copy number 9 (within-gene range 7–9): ZNF514, ZNF2.
- chr2:97,094,935–97,100,874, 2 genes, copy number 9: AC018892.3, RN7SL313P.
- chr2:99,154,955–99,195,298, 3 genes, copy number 9 (within-gene range 7–9): LIPT1, AC092587.1, MITD1.
- chr2:102,967,408–104,147,229, 12 genes, copy number 9: LINC01935, AC108051.1, AC073987.1, AC010881.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1.
- chr2:121,337,776–131,093,460, 163 genes, copy number 9–10 (broad region; genes not listed).
- chr2:164,653,624–169,526,258, 47 genes, copy number 9–10: COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, CSRNP3, GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, RN7SKP152, SCN9A, SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1, AC073050.1, RNU7-148P, CTAGE14P, B3GALT1-AS1, B3GALT1, STK39, PHF5GP, RN7SL813P, CERS6, MIR4774, RNU6-766P, CERS6-AS1, NOSTRIN, SPC25, G6PC2, ABCB11, DHRS9, AC007556.1, UBE2V1P6, LRP2, BBS5, AC093899.2, KLHL41.
- chr2:169,584,342–170,120,098, 13 genes, copy number 9: PPIG, CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P.
- chr2:171,517,270–172,736,206, 23 genes, copy number 9–10 (within-gene range 4–10): RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2.
- chr2:189,311,263–192,776,899, 55 genes, copy number 9: KRT18P19, WDR75, KDM3AP1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2, AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2.
- chr2:193,730,555–194,576,578, 6 genes, copy number 9 (within-gene range 8–9): SEC61GP1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821.
- chr2:195,003,711–196,068,837, 10 genes, copy number 9 (within-gene range 8–9): AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7.
- chr2:196,189,099–198,572,581, 35 genes, copy number 9 (within-gene range 8–9): HECW2, HECW2-AS1, RN7SL820P, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923.
- chr2:198,882,573–201,229,406, 57 genes, copy number 9: AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1, SATB2-AS1, LINC01877, SEPHS1P6, FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1, SPATS2L, RNY4P34, AC012459.1, KCTD18, SGO2, AOX1, AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1, RNU6-31P, BICD1P1, RNA5SP115, CLK1, Y_RNA, PPIL3, RNU6-312P, NIF3L1, RNU6-762P, ORC2, AC005037.1, FAM126B, HNRNPA1P35, RPL23AP30, NDUFB3, RNU6-1206P, Metazoa_SRP, AC007272.1, RPL17P10, CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P, RPL38P5, AC007283.1, CASP10, MTND5P25, MTND4P23, MTND4LP13.
- chr7:1,614,590–1,621,405, 2 genes, copy number 9: TFAMP1, AC074389.2.
- chr8:7,495,911–7,592,916, 7 genes, copy number 9: DEFB107B, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P.
- chr8:98,943,595–100,683,574, 41 genes, copy number 9–10: AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P.
- chr8:100,739,802–100,831,860, 4 genes, copy number 9: RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P.
- chr8:140,505,813–145,066,685, 197 genes, copy number 9–11 (broad region; genes not listed).
- chr10:127,549,309–133,778,699, 115 genes, copy number 9–12 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 11 (broad region; genes not listed).
- chr19:43,192,702–43,269,530, 3 genes, copy number 9: PSG4, CEACAMP10, PSG9.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
